Somatic mutation profile of tumor specimen MMRF_1807_1_BM_CD138pos (aliquot MMRF_1807_1_BM_CD138pos_T1_KBS5U_L05383) from MMRF case MMRF_1807, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 78.1 years (28,543 days).
Specimen MMRF_1807_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3335408e-a913-46dc-afab-3038082d1e0a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1807_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1807_1_PB_Whole_C3_KBS5U_L05396; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52b10f42-c7a4-44ca-863c-f7b2f1c2c93a

The open-access MAF lists 99 somatic variants for this specimen: 38 protein-altering or splice-affecting, 16 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 23, Silent 16, Intron 12, 5'UTR 6, Nonsense Mutation 3, 3'Flank 2, Frame Shift Del 2, RNA 1, 5'Flank 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1436A>T p.D479V | Missense Mutation (SNP) | VAF 6/84 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705800, COSV66705888; called by muse, mutect2
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 12/43 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AFAP1 | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs138842991; called by muse, mutect2, varscan2
- AP3D1 | c.735C>T p.F245= | Splice Region (SNP) | VAF 9/48 reads (19%) | catalogued as rs200473046; called by muse, mutect2, varscan2
- BDKRB2 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs200693201, COSV60014290; called by muse, mutect2, varscan2
- CBX6 | c.146T>A p.L49Q | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53322217; called by muse, mutect2, varscan2
- FAM135A | c.607G>A p.V203M (on ENST00000370479 / NM_001351599.1; = p.V160M on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as rs143901584; called by muse, mutect2, varscan2
- GJA1 | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 30/113 reads (27%) | catalogued as COSV56997108, COSV56997658; called by muse, mutect2, varscan2
- IGHV2-70 | c.125C>G p.T42S | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.53); PolyPhen benign (0.061); catalogued as rs369724963; called by muse, varscan2
- IGLV3-1 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as rs188197731; called by muse, varscan2
- IGLV3-1 | c.290A>C p.Q97P | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs372648481; called by muse, varscan2
- IGLV3-1 | c.335G>C p.S112T | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as rs374018767; called by muse, varscan2
- MUC5AC | c.13451T>C p.V4484A | Missense Mutation (SNP) | VAF 64/265 reads (24%) | SIFT tolerated (0.62); catalogued as rs956393435; called by muse, mutect2, varscan2
- NPAP1 | c.2536G>T p.E846* | Nonsense Mutation (SNP) | VAF 7/160 reads (4%) | catalogued as COSV100274858; called by muse, mutect2
- P2RY4 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 31/35 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375834423, COSV65736611; called by muse, mutect2, varscan2
- POGLUT2 | c.1035C>A p.N345K | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748631320; called by muse, mutect2, varscan2
- SRPK2 | c.32C>A p.S11* | Nonsense Mutation (SNP) | VAF 8/198 reads (4%) | catalogued as COSV100624343; called by muse, mutect2
- UNC13A | c.1577C>T p.T526M | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV53196884, COSV99408778; called by muse, mutect2, varscan2
- USP33 | c.187G>C p.D63H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV62471855; called by muse, mutect2, varscan2
- ZNF224 | c.1512_1513del p.R504Sfs*11 | Frame Shift Del (DEL) | VAF 47/184 reads (26%) | catalogued as rs1386908907; called by pindel, varscan2
- CDKL3 | c.137T>C p.I46T | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2
- CPT1B | c.2104dup p.H702Pfs*17 | Frame Shift Ins (INS) | VAF 19/62 reads (31%) | called by mutect2, pindel, varscan2
- FZD9 | c.1768C>T p.H590Y | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); called by muse, mutect2
- IPO11 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2
- KALRN | c.5770G>A p.A1924T (on ENST00000360013 / NM_001024660.4; = p.A227T on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.771); called by muse, mutect2
- MRC1 | c.4289T>G p.F1430C | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); called by muse, mutect2
- NPTX2 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- PRKCD | c.1301A>G p.D434G | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RHBDF2 | c.8del p.S3Lfs*55 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | called by mutect2, pindel, varscan2
- SCRN1 | c.196T>A p.Y66N | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2
- SLC27A6 | c.178T>A p.F60I | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2
- SNRNP200 | c.4718C>T p.A1573V | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- TELO2 | c.151A>G p.K51E | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2
- TMOD3 | c.238C>A p.H80N | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.375); called by muse, mutect2
- TRABD2A | c.1210T>C p.S404P (on ENST00000409520 / NM_001277053.2; = p.S355P on NM_001080824.3) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- UBASH3B | c.1263G>A p.M421I | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); called by muse, mutect2
- ZBED6 | c.958G>T p.V320F | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZSCAN2 | c.1676G>C p.R559T | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.014); called by muse, mutect2
- CDH11 | c.2283C>T p.A761= | Silent (SNP) | VAF 10/184 reads (5%) | called by muse, mutect2
- CLEC4D | c.240C>A p.T80= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV55228984; called by muse, mutect2, varscan2
- CMTM2 | c.663A>G p.K221= | Silent (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- DNAH11 | c.3042G>A p.Q1014= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs1331705631; called by muse, mutect2, varscan2
- DPYSL5 | c.309C>T p.P103= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as rs757282159; called by muse, mutect2, varscan2
- HEATR5B | c.5076C>T p.A1692= | Silent (SNP) | VAF 34/112 reads (30%) | called by muse, mutect2, varscan2
- HECW1 | c.1785G>A p.S595= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV67835639; called by muse, mutect2, varscan2
- IGLV3-1 | c.99A>G p.P33= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as rs373803208; called by muse, varscan2
- ITPRIP | c.18C>T p.F6= | Silent (SNP) | VAF 33/86 reads (38%) | called by muse, mutect2, varscan2
- KRTAP6-3 | c.249C>T p.G83= | Silent (SNP) | VAF 9/223 reads (4%) | called by muse, mutect2
- PSD3 | c.2844C>T p.A948= (on ENST00000440756; = p.A947= on NM_015310.4) | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as rs1184727176, COSV54074226; called by muse, mutect2, varscan2
- PYM1 | c.271C>T p.L91= | Silent (SNP) | VAF 8/130 reads (6%) | catalogued as COSV56812415; called by muse, mutect2
- ROBO3 | c.1908C>A p.G636= | Silent (SNP) | VAF 52/102 reads (51%) | catalogued as rs1434716732; called by muse, mutect2, varscan2
- TRPC7 | c.660C>T p.N220= | Silent (SNP) | VAF 33/141 reads (23%) | catalogued as COSV61452104; called by muse, mutect2, varscan2
- VGLL4 | c.552C>T p.H184= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as rs1396394290; called by muse, mutect2
- ZNF197 | c.1405C>T p.L469= | Silent (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- ARHGAP5 | c.4182-151G>T | Intron (SNP) | VAF 2/8 reads (25%) | called by muse, mutect2
- ASCC3 | c.*312A>G | 3'UTR (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- ATF4 | c.-747C>T | 5'UTR (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- ATOH8 | c.*316C>T | 3'UTR (SNP) | VAF 20/227 reads (9%) | catalogued as rs1396850027; called by muse, mutect2
- BCL7A | chr12:122021401 G>A | 5'Flank (SNP) | VAF 20/82 reads (24%) | catalogued as rs547304687, COSV55852870; called by muse, mutect2, varscan2
- BMP6 | c.*1088A>G | 3'UTR (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- CD9 | c.*27A>T | 3'UTR (SNP) | VAF 43/138 reads (31%) | called by muse, mutect2, varscan2
- CEP57L1P1 | n.106C>T | RNA (SNP) | VAF 45/153 reads (29%) | called by muse, mutect2, varscan2
- CLIP1 | c.*794A>G | 3'UTR (SNP) | VAF 6/58 reads (10%) | catalogued as rs1027900766; called by muse, mutect2
- DIAPH3 | c.*214_*215insC | 3'UTR (INS) | VAF 6/40 reads (15%) | called by pindel, varscan2*
- DISP1 | c.509+73C>T | Intron (SNP) | VAF 31/74 reads (42%) | catalogued as rs991629329; called by muse, mutect2, varscan2
- DTX1 | c.-455A>T | 5'UTR (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2
- DTX1 | c.-454G>A | 5'UTR (SNP) | VAF 12/28 reads (43%) | catalogued as COSV57495045, COSV57495131; called by mutect2, varscan2
- FIGNL1 | c.*877C>G | 3'UTR (SNP) | VAF 4/74 reads (5%) | catalogued as rs887151084; called by muse, mutect2
- HACD2 | c.*2641G>A | 3'UTR (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- HMGN1 | c.*587G>A | 3'UTR (SNP) | VAF 6/138 reads (4%) | called by muse, mutect2
- HOMEZ | c.-26A>T | 5'UTR (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2, varscan2
- KAT6A | c.-293G>A | 5'UTR (SNP) | VAF 8/28 reads (29%) | catalogued as rs926626938; called by muse, mutect2, varscan2
- KCNAB1 | c.275+22180A>G | Intron (SNP) | VAF 5/57 reads (9%) | catalogued as COSV101050758; called by muse, mutect2
- LRCOL1 | c.*230A>G | 3'UTR (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2
- MACROH2A1 | c.688+2220A>G | Intron (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2, varscan2
- MAPK12 | c.620-26G>A | Intron (SNP) | VAF 18/44 reads (41%) | catalogued as rs1311312724; called by muse, mutect2, varscan2
- NWD1 | c.*1426T>C | 3'UTR (SNP) | VAF 7/82 reads (9%) | called by muse, mutect2
- PDS5A | c.1770+263A>C | Intron (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- PPIG | c.*1160A>G | 3'UTR (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- RAB5A | c.164-4918G>A | Intron (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2, varscan2
- SLC27A1 | c.1206+214del | Intron (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel
- SOX17 | c.*154T>C | 3'UTR (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- SPTBN1 | c.*63C>G | 3'UTR (SNP) | VAF 129/317 reads (41%) | catalogued as COSV100777286; called by muse, mutect2, varscan2
- TBC1D30 | c.*144G>T | 3'UTR (SNP) | VAF 10/32 reads (31%) | catalogued as rs1171112864; called by muse, mutect2, varscan2
- TRPV6 | c.*492G>A | 3'UTR (SNP) | VAF 46/138 reads (33%) | catalogued as rs764034316; called by muse, mutect2, varscan2
- U2SURP | c.*2795G>T | 3'UTR (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2, varscan2
- UBE2H | c.*1548C>G | 3'UTR (SNP) | VAF 25/250 reads (10%) | called by muse, mutect2
- UNC5D | c.*2139T>C | 3'UTR (SNP) | VAF 40/87 reads (46%) | called by muse, mutect2, varscan2
- USF3 | c.*1225G>T | 3'UTR (SNP) | VAF 10/46 reads (22%) | called by muse, varscan2
- USP43 | c.1662+29C>T | Intron (SNP) | VAF 24/70 reads (34%) | catalogued as rs141092400; called by muse, mutect2, varscan2
- WDR77 | c.*155G>A | 3'UTR (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- XKR6 | c.764+76941G>A | Intron (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- YLPM1 | c.6111+155T>A | Intron (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- YLPM1 | c.6111+667T>C | Intron (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2
- ZBTB38 | chr3:141449761 A>G | 3'Flank (SNP) | VAF 4/86 reads (5%) | called by muse, mutect2
- ZDBF2 | c.*1298_*1301del | 3'UTR (DEL) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.-959C>T | 5'UTR (SNP) | VAF 20/34 reads (59%) | called by muse, mutect2, varscan2
- ZNF80 | c.*256G>A | 3'UTR (SNP) | VAF 27/50 reads (54%) | called by muse, mutect2, varscan2
- ZNFX1 | chr20:49243773 C>G | 3'Flank (SNP) | VAF 54/145 reads (37%) | catalogued as rs1298168480; called by muse, mutect2, varscan2
